Somatic mutation profile of tumor specimen TARGET-30-PAIWRB-01A (aliquot TARGET-30-PAIWRB-01A-01D) from TARGET case TARGET-30-PAIWRB, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 2.9 years (1,065 days).
Specimen TARGET-30-PAIWRB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8079d614-fa3a-428e-a8f2-1bb1670fa65a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIWRB-10A (Blood Derived Normal), aliquot TARGET-30-PAIWRB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2b2dbd7-157e-4d6c-b274-75ed7dad05cc

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV51944486; called by muse, mutect2, varscan2
- COL4A4 | c.3131C>A p.P1044Q | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.653); catalogued as COSV61633210; called by muse, mutect2
- FNDC3B | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV61038246; called by muse, mutect2, varscan2
- TRBV19 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs769411579; called by muse, mutect2
- FILIP1 | c.2415C>A p.V805= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
